Somatic mutation profile of tumor specimen MP2PRT-PATWGK-TMP1-A (aliquot MP2PRT-PATWGK-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATWGK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,567 days).
Specimen MP2PRT-PATWGK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa5efc13-5754-410c-b0f0-c75a88e1bb9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWGK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWGK-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aaf5d59-ae29-4b57-8bce-36bca50b1c9c

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1460G>A p.R487H (on ENST00000399959; = p.R488H on NM_001356.5) | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs796052235, CM158043, COSV67864331; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBLN1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1218807619; called by muse, mutect2, varscan2
- NLRP8 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs199762057, COSV52584125; called by muse, mutect2
- NUDT19 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 32/705 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs767914984; called by muse, mutect2
- NUP155 | c.2999G>A p.G1000D (on ENST00000231498 / NM_153485.3; = p.G941D on NM_004298.4) | Missense Mutation (SNP) | VAF 123/590 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763336970; called by muse, mutect2, varscan2
- PCDH11X | c.3725C>A p.A1242D | Missense Mutation (SNP) | VAF 187/363 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); catalogued as COSV53479880; called by muse, mutect2, varscan2
- ZEB2 | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 130/523 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57951889; called by muse, mutect2, varscan2
- GSPT1 | c.1054_1068delinsAGGG p.E352Rfs*5 (on ENST00000420576 / NM_001130007.2; = p.E490Rfs*5 on NM_002094.4) | Frame Shift Del (DEL) | VAF 42/269 reads (16%) | called by pindel, varscan2*
- SPOP | c.383_384insGCATTGGCGATA p.G128_K129insHWRY | In Frame Ins (INS) | VAF 54/266 reads (20%) | called by mutect2, pindel, varscan2
- TRIM72 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 197/527 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHROOM3 | c.3663G>A p.S1221= | Silent (SNP) | VAF 140/459 reads (31%) | catalogued as rs1352254698; called by muse, mutect2, varscan2
